Somatic mutation profile of tumor specimen C3N-05108-04 (aliquot CPT0438590009) from CPTAC case C3N-05108, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.9 years (26,980 days).
Specimen C3N-05108-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2be0844-1a92-4bea-bcbf-f61967190749.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05108-31 (Blood Derived Normal), aliquot CPT0444780005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/208bb918-dd6e-4585-bcae-51b8010b4f99

The open-access MAF lists 614 somatic variants for this specimen: 410 protein-altering or splice-affecting, 179 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 377, Silent 179, Nonsense Mutation 22, Intron 14, Splice Region 7, 5'UTR 3, 3'UTR 3, Splice Site 2, RNA 2, 5'Flank 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 53/596 reads (9%) | catalogued as rs753698250, CM034725, COSV99524658; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 116/453 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 49/356 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876660535, CM041823, CM110163, COSV64289150, COSV64290215, COSV64293195; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 41/519 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs104894289, CM981692, COSV100200812; ClinVar: pathogenic; called by muse, mutect2
- RNF125 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.333); catalogued as rs370242930, CM1412057; ClinVar: pathogenic; called by muse, mutect2
- TTN | c.82631G>A p.W27544* (on ENST00000591111; = p.W20120* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 51/582 reads (9%) | catalogued as rs1057518275, COSV60181511; ClinVar: likely pathogenic; called by muse, mutect2
- ABCD1 | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 52/567 reads (9%) | catalogued as CM950059; called by muse, mutect2
- ABCF2 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV104382757; called by muse, mutect2
- ABLIM1 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 39/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771119867, COSV53301113; called by muse, mutect2, varscan2
- AC099489.1 | c.5143C>T p.Q1715* | Nonsense Mutation (SNP) | VAF 14/400 reads (4%) | catalogued as rs984177483; called by muse, mutect2
- AC109583.1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 32/403 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV58405767; called by muse, mutect2
- ACTN4 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 58/478 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774429535, COSV99400009; called by muse, mutect2, varscan2
- ADAMTS3 | c.300A>C p.Q100H | Missense Mutation (SNP) | VAF 46/621 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs751923787; called by muse, mutect2
- ADGRA2 | c.1840G>A p.V614M | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs757708388, COSV59447812; called by muse, mutect2
- ADGRL2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 46/564 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99592092; called by muse, mutect2
- ADGRV1 | c.2612G>A p.G871E | Missense Mutation (SNP) | VAF 29/481 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767494931, CD1411366; called by muse, mutect2
- AFM | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV56919009; called by muse, mutect2
- AL645922.1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 46/598 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.078); catalogued as rs139113913, COSV54963040; called by muse, mutect2
- ALPK2 | c.6038C>T p.P2013L | Missense Mutation (SNP) | VAF 28/377 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs780252761; called by muse, mutect2
- AMY2A | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs771596779; called by muse, mutect2, varscan2
- ANKRD13C | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 148/606 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs573444936; called by muse, mutect2
- APOB | c.11341C>T p.L3781F | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as rs1558560655; ClinVar: uncertain significance; called by muse, mutect2
- ARID2 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 33/345 reads (10%) | catalogued as COSV100535240, COSV57602529; called by muse, mutect2
- ARSL | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 52/722 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66965029; called by muse, mutect2
- ATP13A4 | c.1625C>T p.T542I | Missense Mutation (SNP) | VAF 58/760 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV55065454, COSV55073632; called by muse, mutect2
- ATP2B2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 60/612 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59492447, COSV59503549; called by muse, mutect2
- BARHL2 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178542684, COSV64981248; called by muse, mutect2, varscan2
- BDNF | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs779034534, COSV59233109; called by muse, mutect2
- BEST3 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 41/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56994844; called by muse, mutect2
- BICC1 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 27/396 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs778196471; called by muse, mutect2
- BPIFA1 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs774194223; called by muse, mutect2, varscan2
- BRAP | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV58155901; called by muse, mutect2
- BRINP2 | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 62/379 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV64176776; called by muse, mutect2, varscan2
- C2orf16 | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 25/373 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1320316195; called by muse, mutect2
- C2orf50 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 55/588 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs138729604; called by muse, mutect2
- CADM2 | c.158C>T p.S53F (on ENST00000407528 / NM_001167674.2; = p.S55F on NM_153184.4) | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV67365107; called by muse, mutect2
- CCDC158 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 35/396 reads (9%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.879); catalogued as COSV66356475; called by muse, mutect2
- CCDC73 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1462940314, COSV58795902; called by muse, mutect2
- CD7 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 60/668 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as COSV53940453; called by muse, mutect2
- CDC20B | c.237A>C p.Q79H | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV57051504, COSV57054667; called by muse, mutect2
- CDC45 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 47/380 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs780120444, COSV54243447; called by muse, mutect2, varscan2
- CDH6 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 43/526 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV54064326; called by muse, mutect2
- CDH8 | c.2275C>T p.L759F | Missense Mutation (SNP) | VAF 52/706 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184600; called by muse, mutect2
- CDH8 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 40/582 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1186062045, COSV54905548; called by muse, mutect2
- CDHR2 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV99992061; called by muse, mutect2
- CFAP47 | c.5163C>A p.S1721R | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs767628108; called by muse, mutect2, varscan2
- CLEC3A | c.205G>A p.E69K (on ENST00000651443; = p.E60K on NM_005752.6) | Missense Mutation (SNP) | VAF 31/452 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV55219916; called by muse, mutect2
- CLEC4D | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV55230559; called by muse, mutect2
- CNGA4 | c.63G>A p.R21= | Splice Region (SNP) | VAF 27/292 reads (9%) | catalogued as rs1442671464, COSV56410229; called by muse, mutect2
- CNGB1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.05); catalogued as COSV51905884; called by muse, mutect2, varscan2
- COL11A1 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 110/507 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV62183504; called by muse, mutect2, varscan2
- COL1A2 | c.1901G>A p.G634D | Missense Mutation (SNP) | VAF 84/480 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM930152; called by muse, mutect2, varscan2
- COLEC10 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60521978; called by muse, mutect2
- CPA3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199600994, COSV56044010; called by muse, mutect2
- CPD | c.3498G>A p.K1166= | Splice Region (SNP) | VAF 29/271 reads (11%) | catalogued as rs755451558; called by muse, mutect2, varscan2
- CPXCR1 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 55/504 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV52162836; called by muse, mutect2, varscan2
- CSMD3 | c.9974G>A p.G3325E (on ENST00000297405 / NM_001363185.1; = p.G3156E on NM_052900.3) | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036367099; called by muse, mutect2
- DACH1 | c.1565G>A p.R522Q (on ENST00000619232 / NM_001366712.1; = p.R470Q on NM_080759.6) | Missense Mutation (SNP) | VAF 55/498 reads (11%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.006); catalogued as rs762011848, COSV57487825, COSV57491033, COSV57495587; called by muse, mutect2, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 53/688 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2
- DCDC1 | c.2127G>A p.M709I | Missense Mutation (SNP) | VAF 21/303 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as COSV60839976; called by muse, mutect2
- DMRTB1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 154/536 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs749298992, COSV65113142; called by muse, mutect2, varscan2
- DNAH10 | c.4528G>A p.G1510R (on ENST00000409039; = p.G1449R on NM_207437.3) | Missense Mutation (SNP) | VAF 45/653 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs777370881; called by muse, mutect2
- DNASE1L3 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as rs867139693, COSV100568791, COSV59155950; called by muse, mutect2
- DSC1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 37/502 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as rs1304987574, COSV57142195; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 38/427 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as rs1272679401, COSV100201165; called by muse, mutect2
- EGFR | c.566A>G p.K189R | Missense Mutation (SNP) | VAF 33/365 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV51790826; called by muse, mutect2
- EPB41L4B | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100775844; called by muse, mutect2
- EPG5 | c.7511G>A p.R2504H | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs979554550, COSV56347470; called by muse, mutect2
- EPHB3 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1171159383, COSV100383355; called by muse, mutect2, varscan2
- ERN2 | c.1087C>T p.H363Y | Missense Mutation (SNP) | VAF 75/421 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV99890827; called by muse, mutect2, varscan2
- FAM170A | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1248975461, COSV104407083; called by muse, mutect2
- FLG2 | c.2590A>C p.S864R | Missense Mutation (SNP) | VAF 48/718 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV66170521; called by muse, mutect2
- FNDC1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 46/436 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.318); catalogued as COSV51938094; called by muse, mutect2, varscan2
- FOXP4 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs764800851; called by muse, mutect2
- GAB3 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 35/383 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs782602979, COSV65819042; called by muse, mutect2, varscan2
- GLI1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs774885952, COSV99954306; called by muse, mutect2
- GNPAT | c.1918G>A p.V640I | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as rs1408478501; called by muse, mutect2, varscan2
- GON4L | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 46/557 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as COSV55187570, COSV99673999; called by muse, mutect2
- GRIN3A | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 44/516 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs201751805; called by muse, mutect2
- GRM8 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 35/412 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs755371409; called by muse, mutect2
- GUCY2F | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 39/628 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs752859763, COSV54300867; called by muse, mutect2
- HCRTR2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1309521748, COSV63797395; called by muse, mutect2
- HEPHL1 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.438); catalogued as COSV59889344; called by muse, mutect2
- HNRNPCL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/228 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.074); catalogued as rs932249755, COSV100508848; called by muse, mutect2, varscan2
- HOXB1 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 56/518 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs200541812, COSV53317805, COSV53317930; called by muse, mutect2, varscan2
- HRG | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 90/1048 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as COSV99214495; called by muse, mutect2
- HUWE1 | c.3907G>A p.D1303N | Missense Mutation (SNP) | VAF 50/619 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs782804715, COSV53363562; called by muse, mutect2
- IGKV4-1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs753538474; called by muse, mutect2
- IGSF9 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 70/378 reads (19%) | catalogued as rs1031642878; called by muse, mutect2, varscan2
- IL3RA | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 34/468 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs763856144, COSV58429908; called by muse, mutect2
- INO80D | c.1299C>A p.S433R | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1278402953; called by muse, mutect2, varscan2
- INS | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 41/504 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.067); catalogued as rs1240250526; called by muse, mutect2
- IQCA1 | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1410995798, COSV54496527; called by muse, mutect2
- KASH5 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 37/382 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375328950; called by muse, mutect2
- KIAA2012 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 52/618 reads (8%) | catalogued as rs1233329213; called by muse, mutect2
- KIF13B | c.5329C>T p.R1777C | Missense Mutation (SNP) | VAF 47/667 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs552142818; called by muse, mutect2
- KRBOX4 | c.454G>A p.A152T (on ENST00000344302 / NM_001129898.2; = p.A147T on NM_017776.2) | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99994368; called by muse, mutect2
- KRT24 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 44/553 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs200612551; called by muse, mutect2
- L1TD1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs771642989, COSV63133649, COSV63134389; called by muse, mutect2, varscan2
- LAMB1 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 59/636 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151243430; called by muse, mutect2
- LARP4B | c.1698C>T p.T566= | Splice Region (SNP) | VAF 24/255 reads (9%) | catalogued as rs1033520687; called by muse, mutect2
- LATS2 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 56/693 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV66877743; called by muse, mutect2
- LATS2 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 56/660 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs753049071; called by muse, mutect2
- LATS2 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 55/662 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs758975100; called by muse, mutect2
- LMNTD2 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 54/702 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1249276398; called by muse, mutect2
- LRRC49 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs866260364; called by muse, mutect2
- LRRIQ4 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 52/628 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs370499289; called by muse, mutect2
- LSR | c.1224G>A p.M408I (on ENST00000361790; = p.M389I on NM_015925.6) | Missense Mutation (SNP) | VAF 38/531 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.385); catalogued as rs558989058; called by muse, mutect2
- LUM | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 34/471 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV57127963; called by muse, mutect2
- MAGEC1 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 44/586 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99596196; called by muse, mutect2
- MED13L | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 41/406 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1425933908, COSV56125227; called by muse, mutect2
- MEGF8 | c.8168C>T p.P2723L (on ENST00000251268 / NM_001271938.2; = p.P2656L on NM_001410.3) | Missense Mutation (SNP) | VAF 51/666 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.081); catalogued as COSV52094487; called by muse, mutect2
- MEIS2 | c.755G>A p.G252E (on ENST00000561208 / NM_170675.5; = p.G239E on NM_002399.3) | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV99576006; called by muse, mutect2
- MLIP | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.52); catalogued as rs868484746; called by muse, mutect2
- MS4A6E | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752908828, COSV55726872; called by muse, mutect2
- MUC5B | c.13003G>A p.G4335R | Missense Mutation (SNP) | VAF 58/702 reads (8%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs376719823; called by muse, mutect2
- MYH8 | c.2996A>C p.K999T | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as rs1411515344; called by muse, mutect2, varscan2
- MYO3B | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV58700329; called by muse, mutect2
- MYT1L | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 49/571 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs1489543411, COSV67720855; called by muse, mutect2
- NAV3 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 52/550 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.015); catalogued as rs189238808, COSV99887918; called by muse, mutect2
- NCKAP5 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 31/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1277595428; called by muse, mutect2
- NCL | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs1325330775, COSV59545551; called by muse, mutect2
- NETO1 | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV55000890; called by muse, mutect2, varscan2
- NEUROD6 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 76/578 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.227); catalogued as rs746343771, COSV51770445; called by muse, mutect2, varscan2
- NLRP2 | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 42/652 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as COSV54760245; called by muse, mutect2
- NLRP3 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 87/483 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs199696688, COSV60219638; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP5 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs775602942; called by muse, mutect2
- NMBR | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as rs1466390519, COSV57800598; called by muse, mutect2
- NPC1L1 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs139575026; called by muse, mutect2, varscan2
- NR0B1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 58/778 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as COSV66763708; called by muse, mutect2
- NR2F1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 47/540 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59067896; called by muse, mutect2
- NRK | c.4426T>C p.F1476L | Missense Mutation (SNP) | VAF 35/620 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1277323553; called by muse, mutect2
- NXF3 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 35/393 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1432949810, COSV67703010; called by muse, mutect2
- OPRPN | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 48/544 reads (9%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV68193321; called by muse, mutect2
- OR10G4 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 47/516 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57977129; called by muse, mutect2, varscan2
- OR5D14 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 37/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59458314; called by muse, mutect2
- OR5J2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 40/556 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364673970, COSV56620315; called by muse, mutect2
- OR6A2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 31/461 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60264783; called by muse, mutect2
- OR6C75 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 52/586 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.167); catalogued as COSV58551919; called by muse, mutect2
- OR6T1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 54/606 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV58306859, COSV58308509; called by muse, mutect2
- OTOG | c.6550C>T p.R2184C | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs756197661; called by muse, mutect2
- P2RY4 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 65/742 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV65736241, COSV65736398; called by muse, mutect2
- PAPLN | c.3185G>T p.R1062L (on ENST00000554301; = p.R1035L on NM_173462.4) | Missense Mutation (SNP) | VAF 50/687 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53724251; called by muse, mutect2
- PARPBP | c.536A>G p.N179S | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1288870119; called by muse, mutect2
- PCDH15 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV57288789; called by muse, mutect2
- PCDHA2 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 57/575 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV100974162; called by muse, mutect2
- PCDHA5 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 23/367 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65352168, COSV65352412; called by muse, mutect2
- PEG3 | c.3446C>T p.S1149F | Missense Mutation (SNP) | VAF 33/424 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs772166672; called by muse, mutect2
- PEG3 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 43/490 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55638839; called by muse, mutect2
- PI4KA | c.4381G>A p.G1461S | Missense Mutation (SNP) | VAF 57/347 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.015); catalogued as rs565662495; called by muse, mutect2, varscan2
- PIEZO2 | c.5750C>T p.T1917I | Missense Mutation (SNP) | VAF 58/606 reads (10%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.865); catalogued as rs1280736752; called by muse, mutect2
- PIK3CG | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 42/538 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.586); catalogued as rs1251220989, COSV100782573; called by muse, mutect2
- PKHD1L1 | c.2687G>A p.S896N | Missense Mutation (SNP) | VAF 27/388 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.572); catalogued as rs767162051; called by muse, mutect2
- PLCB4 | c.623A>C p.K208T | Missense Mutation (SNP) | VAF 29/399 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV53803343; called by muse, mutect2
- PLCH1 | c.4688C>T p.S1563L (on ENST00000340059 / NM_001130960.2; = p.S1555L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/531 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV58201551; called by muse, mutect2
- PLCL2 | c.1006C>T p.H336Y (on ENST00000615277 / NM_001144382.2; = p.H210Y on NM_015184.5) | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.424); catalogued as COSV67621802; called by muse, mutect2
- PLCZ1 | c.40T>C p.F14L | Missense Mutation (SNP) | VAF 15/295 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV56849392, COSV56852893; called by muse, mutect2
- PMFBP1 | c.1783C>T p.R595C (on ENST00000537465; = p.R590C on NM_031293.3) | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs149578677, COSV99401367; called by muse, mutect2
- PNCK | c.241G>A p.E81K (on ENST00000340888 / NM_001366975.1; = p.E164K on NM_001039582.3) | Missense Mutation (SNP) | VAF 50/502 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100562231; called by muse, mutect2
- POF1B | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53138544; called by muse, mutect2
- PPL | c.2801G>A p.R934K | Missense Mutation (SNP) | VAF 66/478 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1295620878; called by muse, mutect2, varscan2
- PROM2 | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs756684142; called by muse, mutect2
- PRSS55 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 50/604 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.092); catalogued as COSV60807834; called by muse, mutect2
- PSG8 | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1288395334; called by muse, mutect2
- PSG9 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 51/458 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52489771; called by muse, mutect2, varscan2
- PTCHD1 | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV101037745; called by muse, mutect2
- RAC3 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 33/417 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1322924150; called by muse, mutect2
- REV3L | c.8816G>A p.R2939Q | Missense Mutation (SNP) | VAF 20/315 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs569959075; called by muse, mutect2
- RNF133 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs769856521; called by muse, mutect2
- ROBO4 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 48/674 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as rs769525351; called by muse, mutect2
- RP1 | c.5512C>T p.R1838C | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs1240493980, COSV55123358; called by muse, mutect2
- RPL10 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 32/339 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV50009974; called by muse, mutect2, varscan2
- RSPO2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 49/600 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs182334537, COSV52639993; called by muse, mutect2
- RYR1 | c.5671G>A p.E1891K | Missense Mutation (SNP) | VAF 61/698 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.202); catalogued as rs990397545; called by muse, mutect2
- SDR42E1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 74/469 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV61094187; called by muse, mutect2, varscan2
- SDR42E2 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs903089124, COSV58308710; called by muse, mutect2
- SLC16A7 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53894129; called by muse, mutect2
- SLC16A7 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53900195; called by muse, mutect2
- SLC22A8 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 64/726 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs201611920; called by muse, mutect2
- SLC25A19 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as rs755619240; called by muse, mutect2
- SLC4A10 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.132); catalogued as COSV99761822; called by muse, mutect2
- SLC4A10 | c.2270G>A p.R757Q (on ENST00000446997 / NM_001354461.2; = p.R727Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs769463278, COSV55788128; called by muse, mutect2
- SLC8A3 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 36/401 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV63522502; called by muse, mutect2
- SORCS3 | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV100864561; called by muse, mutect2, varscan2
- SPHKAP | c.4910G>A p.G1637E (on ENST00000392056 / NM_001142644.2; = p.G1608E on NM_030623.3) | Missense Mutation (SNP) | VAF 47/486 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60875234; called by muse, mutect2
- ST8SIA3 | c.911T>G p.L304R | Missense Mutation (SNP) | VAF 50/466 reads (11%) | PolyPhen probably damaging (0.913); catalogued as COSV60654350; called by muse, mutect2, varscan2
- STAB2 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs751339383, COSV101186308, COSV66348673; called by muse, mutect2
- STAB2 | c.3950G>A p.R1317Q | Missense Mutation (SNP) | VAF 32/473 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.86); catalogued as rs763409318, COSV66338311; called by muse, mutect2
- STAG2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 40/485 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV54368564; called by muse, mutect2
- STXBP5L | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs561846083, COSV56522382; called by muse, mutect2
- TAAR5 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 23/267 reads (9%) | catalogued as COSV99236970; called by muse, mutect2
- TACC2 | c.5932G>A p.E1978K (on ENST00000334433; = p.E56K on NM_006997.4) | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs961067010; called by muse, mutect2
- TAF7 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.019); catalogued as rs753555262; called by muse, mutect2, varscan2
- TAGAP | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 48/519 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as rs1562584529, COSV57853224; called by muse, mutect2
- TAOK2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 29/437 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1273066702; called by muse, mutect2
- TAX1BP1 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.529); catalogued as COSV55295720, COSV55296241; called by muse, mutect2
- TBX3 | c.1058C>T p.S353F (on ENST00000257566 / NM_016569.4; = p.S333F on NM_005996.4) | Missense Mutation (SNP) | VAF 23/462 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57476904; called by muse, mutect2
- TET2 | c.3700G>T p.E1234* | Nonsense Mutation (SNP) | VAF 32/457 reads (7%) | catalogued as COSV54405749; called by muse, mutect2
- TEX19 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 55/492 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV100331072; called by muse, mutect2, varscan2
- TLL1 | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 29/467 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV50290317; called by muse, mutect2
- TNR | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 43/264 reads (16%) | catalogued as rs776846663, COSV54867827; called by muse, mutect2, varscan2
- TRAPPC12 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 75/760 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.183); catalogued as rs1402241939; called by muse, mutect2
- TRIM36 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs781088536; called by muse, mutect2
- TRIOBP | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 44/789 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.421); catalogued as rs372225807; called by muse, mutect2
- TRPC7 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 55/432 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as rs544029791, COSV61453683; called by muse, mutect2, varscan2
- TTN | c.39181G>A p.D13061N (on ENST00000591111; = p.D5637N on NM_003319.4) | Missense Mutation (SNP) | VAF 46/375 reads (12%) | PolyPhen possibly damaging (0.856); catalogued as COSV60264510; called by muse, mutect2, varscan2
- TTN | c.24871G>A p.E8291K (on ENST00000591111; = p.E7364K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/554 reads (8%) | PolyPhen possibly damaging (0.788); catalogued as COSV100605131, COSV59911623; called by muse, mutect2
- TTN | c.9442C>T p.R3148C (on ENST00000591111; = p.R3102C on NM_003319.4) | Missense Mutation (SNP) | VAF 35/468 reads (7%) | PolyPhen probably damaging (0.998); catalogued as rs372196051, COSV59954093; ClinVar: uncertain significance; called by muse, mutect2
- UGT1A6 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 38/557 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV59400474; called by muse, mutect2
- UGT2A1 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 68/643 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV54146381; called by muse, mutect2
- WDFY3 | c.6823C>T p.R2275C | Missense Mutation (SNP) | VAF 31/564 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1306992677, COSV55700591; called by muse, mutect2
- WEE2 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 27/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101285144; called by muse, mutect2
- ZNF595 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 20/639 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV100227893; called by muse, mutect2
- ZNF728 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.897); catalogued as rs766049645, COSV101655252; called by muse, mutect2
- AATK | c.3800T>C p.L1267P (on ENST00000326724 / NM_001080395.3; = p.L1164P on NM_004920.2) | Missense Mutation (SNP) | VAF 63/582 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2
- ACTL6B | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 46/658 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.676); called by muse, mutect2
- ACTR6 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADAMTS7 | c.4902C>T p.P1634= | Splice Region (SNP) | VAF 32/417 reads (8%) | called by muse, mutect2
- ADGRF5 | c.3166A>T p.N1056Y | Missense Mutation (SNP) | VAF 34/500 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRV1 | c.2611G>A p.G871R | Missense Mutation (SNP) | VAF 29/480 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRV1 | c.7246C>T p.Q2416* | Nonsense Mutation (SNP) | VAF 47/565 reads (8%) | called by muse, mutect2
- AFF2 | c.2746C>T p.P916S | Missense Mutation (SNP) | VAF 50/608 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.048); called by muse, mutect2
- AKAP11 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- AKAP5 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- ALG1L | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.255); called by muse, mutect2
- ALPK2 | c.4663G>A p.V1555I | Missense Mutation (SNP) | VAF 51/443 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ANAPC1 | c.1814T>C p.V605A | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.073); called by muse, mutect2
- ANKK1 | c.1549G>A p.G517R | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2
- ARPIN | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ATAD5 | c.4951G>C p.E1651Q | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP13A5 | c.3315+1G>A p.X1105_splice | Splice Site (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- BACE2 | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 42/609 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- BAG6 | c.1892G>A p.G631E (on ENST00000676571; = p.G584E on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/1056 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- BRINP3 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- BSN | c.3965C>T p.S1322F | Missense Mutation (SNP) | VAF 67/681 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- BX276092.9 | c.989A>C p.E330A | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by mutect2, varscan2
- C10orf71 | c.3991C>T p.P1331S | Missense Mutation (SNP) | VAF 50/602 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- C2CD6 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 46/526 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.813); called by muse, mutect2
- C6 | c.1154A>C p.E385A | Missense Mutation (SNP) | VAF 27/290 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2
- C8orf34 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 40/534 reads (7%) | called by muse, mutect2
- CACNA1C | c.5557G>A p.E1853K | Missense Mutation (SNP) | VAF 56/507 reads (11%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALCR | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CATSPERB | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 36/534 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC175 | c.1406G>A p.W469* | Nonsense Mutation (SNP) | VAF 32/432 reads (7%) | called by muse, mutect2
- CD109 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- CD33 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 36/610 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.906); called by muse, mutect2
- CD40LG | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 52/658 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- CFTR | c.3331T>G p.F1111V | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHD2 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 33/457 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COG2 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 53/395 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL12A1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 30/367 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL21A1 | c.1376A>G p.D459G | Missense Mutation (SNP) | VAF 37/406 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.5); called by muse, mutect2
- COL6A5 | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A5 | c.4310G>A p.G1437E | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CR1 | c.5003A>C p.N1668T | Missense Mutation (SNP) | VAF 53/563 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.147); called by muse, mutect2
- CUX2 | c.662T>G p.L221R | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYP11B2 | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 37/612 reads (6%) | called by muse, mutect2
- CYP2B6 | c.476A>T p.K159I | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by mutect2, varscan2
- CYRIA | c.389A>C p.E130A | Missense Mutation (SNP) | VAF 43/528 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2
- DDO | c.784G>A p.E262K (on ENST00000368924 / NM_001368172.1; = p.E203K on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/573 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2
- DENND1C | c.2023C>T p.L675F | Missense Mutation (SNP) | VAF 66/623 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- DGKK | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 45/364 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DHCR7 | c.359A>T p.K120M | Missense Mutation (SNP) | VAF 37/468 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2
- DKC1 | c.250G>T p.G84W | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- DMRTB1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 154/531 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH10 | c.733C>T p.P245S (on ENST00000409039; = p.P184S on NM_207437.3) | Missense Mutation (SNP) | VAF 43/571 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.005); called by muse, mutect2
- DNAH10 | c.4529G>A p.G1510E (on ENST00000409039; = p.G1449E on NM_207437.3) | Missense Mutation (SNP) | VAF 45/656 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- DNAH5 | c.10141T>A p.F3381I | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2
- DNAH6 | c.3145T>A p.F1049I | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- DNAH6 | c.5049A>C p.K1683N | Missense Mutation (SNP) | VAF 18/339 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH9 | c.2747T>G p.L916R | Missense Mutation (SNP) | VAF 34/443 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2
- DNAJC11 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 99/422 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- DOCK11 | c.3158G>A p.G1053E | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.299); called by muse, mutect2
- DOCK6 | c.4338G>A p.K1446= | Splice Region (SNP) | VAF 35/323 reads (11%) | called by muse, mutect2, varscan2
- DSCAM | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- DSG1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 43/486 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2
- DUOX2 | c.4150G>A p.G1384R | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DUSP16 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 46/459 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- EHBP1 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EML6 | c.4590G>A p.M1530I | Missense Mutation (SNP) | VAF 54/528 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- ENPP4 | c.944T>G p.I315S | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- ERICH3 | c.3161T>C p.L1054S | Missense Mutation (SNP) | VAF 97/431 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- EYA4 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 40/533 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.03); called by muse, mutect2
- FAM20A | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 48/542 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2
- FBXL19 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 82/1013 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.07); called by muse, mutect2
- FCRL5 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 72/494 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- FEZ1 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 44/470 reads (9%) | called by muse, mutect2
- FREM1 | c.6167G>T p.G2056V | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GCNT4 | c.365A>C p.K122T | Missense Mutation (SNP) | VAF 42/555 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.142); called by muse, mutect2
- GDF3 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.027); called by muse, mutect2
- GPC3 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 49/683 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2
- GPR82 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 49/672 reads (7%) | called by muse, mutect2
- GUCY2C | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- GUCY2F | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 38/623 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); called by muse, mutect2
- HECTD4 | c.12894C>T p.A4298= | Splice Region (SNP) | VAF 30/307 reads (10%) | called by muse, mutect2
- HS3ST3A1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 41/552 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- HUWE1 | c.3909T>A p.D1303E | Missense Mutation (SNP) | VAF 50/616 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HYDIN | c.7723G>A p.D2575N | Missense Mutation (SNP) | VAF 49/600 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- HYDIN | c.6173A>C p.K2058T | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2
- HYDIN | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 42/483 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- ICA1 | c.745A>T p.M249L | Missense Mutation (SNP) | VAF 80/479 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- IFNAR1 | c.788A>T p.H263L | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- IGHV6-1 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- JADE3 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 38/585 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.084); called by muse, mutect2
- KANSL1 | c.3032A>T p.H1011L (on ENST00000574590 / NM_001193465.2; = p.H1012L on NM_015443.4) | Missense Mutation (SNP) | VAF 74/830 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- KDM4D | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 79/649 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KIAA1210 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 48/616 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); called by muse, mutect2
- KLF14 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 128/697 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2B | c.3619T>A p.C1207S | Missense Mutation (SNP) | VAF 46/573 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LANCL3 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 69/777 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- LCT | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 52/582 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2
- LY9 | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 35/618 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- MAEL | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 76/398 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- MAGEA3 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 42/886 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MALRD1 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 39/430 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- MDC1 | c.1397A>T p.N466I | Missense Mutation (SNP) | VAF 78/727 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.276); called by mutect2, varscan2
- MDGA1 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 64/660 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- MEFV | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 42/580 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); called by muse, mutect2
- MEP1B | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by muse, mutect2
- MICAL1 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MUC16 | c.35099C>T p.P11700L | Missense Mutation (SNP) | VAF 36/497 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); called by muse, mutect2
- MUC16 | c.11877T>G p.S3959R | Missense Mutation (SNP) | VAF 32/554 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.076); called by muse, mutect2
- MXRA5 | c.3394C>T p.P1132S | Missense Mutation (SNP) | VAF 66/755 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2
- MYH13 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYH15 | c.4162G>A p.E1388K | Missense Mutation (SNP) | VAF 40/449 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2
- MYH4 | c.5002C>T p.Q1668* | Nonsense Mutation (SNP) | VAF 46/391 reads (12%) | called by muse, mutect2, varscan2
- MYH7 | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2
- MYO16 | c.889T>C p.S297P | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- NALCN | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.115); called by muse, mutect2
- NCAN | c.2898A>G p.I966M | Missense Mutation (SNP) | VAF 36/620 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2
- NEB | c.1115T>G p.L372R | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP7 | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 98/964 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2
- OR4E1 | c.333T>A p.F111L | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4Q2 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR5H8 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 23/315 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- OR9A4 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 48/654 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- ORC3 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 39/512 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- OTUD7B | c.2460del p.C821Vfs*7 | Frame Shift Del (DEL) | VAF 104/531 reads (20%) | called by mutect2, pindel, varscan2
- OXTR | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 41/602 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.593); called by muse, mutect2
- PARD3 | c.3911C>T p.S1304F | Missense Mutation (SNP) | VAF 56/584 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.309); called by muse, mutect2
- PDGFC | c.229T>G p.L77V | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHF10 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2
- PHF10 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 29/356 reads (8%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- PI4KA | c.3148C>G p.R1050G | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3C2G | c.2114A>G p.Q705R (on ENST00000676171; = p.Q664R on NM_004570.5) | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2
- PIP5K1B | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PLS1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 18/357 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2
- PNPLA4 | c.575C>A p.P192Q | Missense Mutation (SNP) | VAF 55/611 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP1R37 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 46/660 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); called by muse, mutect2
- PRMT8 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 61/436 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPF40A | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- PSD4 | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 51/581 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- PTPRF | c.3377C>T p.P1126L | Missense Mutation (SNP) | VAF 129/445 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRT | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2
- QPCT | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 33/451 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.19); called by muse, mutect2
- RAB3IP | c.260C>T p.S87F (on ENST00000550536 / NM_175623.4; = p.S71F on NM_022456.5) | Missense Mutation (SNP) | VAF 32/423 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); called by muse, mutect2
- RABL6 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- RASAL3 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); called by muse, mutect2
- RBM23 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- RBMX2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 39/635 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2
- RIMS1 | c.899C>G p.P300R | Missense Mutation (SNP) | VAF 48/602 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2
- RIPK1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 40/553 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2
- RNF213 | c.13774C>A p.L4592M | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- RPS6KA6 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 37/453 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- SAMD9L | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 52/624 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); called by muse, mutect2
- SCNN1G | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 48/685 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2
- SELP | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 55/414 reads (13%) | called by muse, mutect2, varscan2
- SF3B1 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.303); called by muse, mutect2
- SLC13A2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.042); called by muse, mutect2
- SLC24A3 | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 38/438 reads (9%) | called by muse, mutect2
- SLC35B1 | c.679C>T p.Q227* (on ENST00000649906; = p.Q190* on NM_005827.4) | Nonsense Mutation (SNP) | VAF 22/408 reads (5%) | called by muse, mutect2
- SLC38A1 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.076); called by muse, mutect2
- SLC4A8 | c.3243G>A p.M1081I | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- SLC6A4 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); called by muse, mutect2
- SNRPA1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 43/393 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SPATA48 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 64/470 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SPEF2 | c.3869A>T p.E1290V | Missense Mutation (SNP) | VAF 52/578 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2
- SQLE | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- SSBP2 | c.571-8C>T | Splice Region (SNP) | VAF 32/318 reads (10%) | called by muse, varscan2
- SULT1C3 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 31/380 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.311); called by muse, mutect2
- SYTL3 | c.1612A>T p.S538C (on ENST00000611299 / NM_001242394.1; = p.S470C on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/564 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- TAAR8 | c.106A>C p.T36P | Missense Mutation (SNP) | VAF 52/568 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2
- TCAF2 | c.2628A>C p.K876N (on ENST00000441159 / NM_001363538.2; = p.K772N on NM_001130026.2) | Missense Mutation (SNP) | VAF 43/360 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TENM4 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2
- TEX13B | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 52/823 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- TEX13C | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 79/900 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.846); called by muse, mutect2
- TGM6 | c.990G>A p.W330* | Nonsense Mutation (SNP) | VAF 41/321 reads (13%) | called by muse, mutect2, varscan2
- THSD7B | c.3992C>T p.S1331F (on ENST00000272643; = p.S1329F on NM_001316349.2) | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- TIAM2 | c.2062C>T p.H688Y | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2
- TMEM134 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- TMEM40 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- TMEM9B | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.022); called by muse, mutect2
- TMPRSS11A | c.880A>C p.I294L | Missense Mutation (SNP) | VAF 44/582 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2
- TMPRSS11E | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 46/439 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- TMPRSS15 | c.1145T>G p.F382C | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- TP63 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 33/423 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAV8-4 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TRIM49B | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TRIM49C | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- TTN | c.75914A>T p.D25305V (on ENST00000591111; = p.D17881V on NM_003319.4) | Missense Mutation (SNP) | VAF 34/510 reads (7%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.55953G>A p.W18651* (on ENST00000591111; = p.W11227* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 46/570 reads (8%) | called by muse, mutect2
- TULP4 | c.4414C>T p.P1472S | Missense Mutation (SNP) | VAF 48/600 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TVP23C | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 40/470 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2
- UBE3D | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 39/453 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- UNC79 | c.7070T>G p.F2357C (on ENST00000393151 / NM_001346218.2; = p.F2180C on NM_020818.5) | Missense Mutation (SNP) | VAF 55/528 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- VWF | c.4876G>C p.V1626L | Missense Mutation (SNP) | VAF 40/476 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- VWF | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.501); called by muse, mutect2
- WWOX | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 34/510 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZIC5 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.641); called by muse, mutect2
- ZNF12 | c.1762C>T p.Q588* (on ENST00000405858 / NM_016265.4; = p.Q550* on NM_006956.3) | Nonsense Mutation (SNP) | VAF 46/630 reads (7%) | called by muse, mutect2
- ACAA1 | c.288C>T p.A96= | Silent (SNP) | VAF 43/566 reads (8%) | catalogued as rs148457692; called by muse, mutect2
- ACSM5 | c.213C>T p.H71= | Silent (SNP) | VAF 53/368 reads (14%) | called by muse, mutect2, varscan2
- ADAM20 | c.18C>T p.P6= | Silent (SNP) | VAF 42/556 reads (8%) | called by muse, mutect2
- ADAM28 | c.1212C>T p.I404= | Silent (SNP) | VAF 36/530 reads (7%) | catalogued as rs865847598; called by muse, mutect2
- ADAM29 | c.2028C>T p.F676= | Silent (SNP) | VAF 31/440 reads (7%) | called by muse, mutect2
- ADAMDEC1 | c.933G>A p.G311= | Silent (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- ADD2 | c.306C>T p.F102= | Silent (SNP) | VAF 34/382 reads (9%) | catalogued as COSV52473259; called by muse, mutect2
- ADGRV1 | c.1795A>C p.R599= | Silent (SNP) | VAF 22/346 reads (6%) | called by muse, mutect2
- ADGRV1 | c.12003C>T p.F4001= | Silent (SNP) | VAF 41/526 reads (8%) | called by muse, mutect2
- ADGRV1 | c.15645C>T p.S5215= | Silent (SNP) | VAF 56/600 reads (9%) | catalogued as rs367798570; called by muse, mutect2
- AFM | c.1719C>T p.F573= | Silent (SNP) | VAF 54/595 reads (9%) | catalogued as rs766941334, COSV56918945; called by muse, mutect2
- ARPP21 | c.738C>T p.S246= | Silent (SNP) | VAF 42/466 reads (9%) | called by muse, mutect2
- ARSL | c.711C>T p.L237= | Silent (SNP) | VAF 50/714 reads (7%) | called by muse, mutect2
- ATAD2B | c.3786C>T p.F1262= | Silent (SNP) | VAF 40/400 reads (10%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.1299C>T p.S433= | Silent (SNP) | VAF 69/618 reads (11%) | called by muse, mutect2, varscan2
- ATP6V1F | c.312C>T p.S104= | Silent (SNP) | VAF 79/536 reads (15%) | catalogued as rs1297162442, COSV50800316; called by muse, mutect2, varscan2
- BIN1 | c.924C>T p.P308= (on ENST00000316724 / NM_001320642.1; = p.P292= on NM_004305.4) | Silent (SNP) | VAF 81/852 reads (10%) | catalogued as rs367611371; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- CACNA2D1 | c.2217G>A p.G739= (on ENST00000356253 / NM_001366867.1; = p.G727= on NM_000722.4) | Silent (SNP) | VAF 32/446 reads (7%) | called by muse, mutect2
- CAPRIN2 | c.1314C>T p.S438= | Silent (SNP) | VAF 48/507 reads (9%) | catalogued as COSV51832693; called by muse, mutect2
- CAVIN2 | c.270G>A p.V90= | Silent (SNP) | VAF 31/583 reads (5%) | catalogued as COSV58423316; called by muse, mutect2
- CBY2 | c.186C>T p.L62= | Silent (SNP) | VAF 38/471 reads (8%) | catalogued as COSV60117863; called by muse, mutect2
- CCDC39 | c.480C>T p.L160= | Silent (SNP) | VAF 32/448 reads (7%) | called by muse, mutect2
- CDH17 | c.75G>A p.G25= | Silent (SNP) | VAF 40/432 reads (9%) | catalogued as COSV50325644; called by muse, mutect2
- CDH20 | c.363G>A p.R121= | Silent (SNP) | VAF 51/577 reads (9%) | catalogued as COSV53010114, COSV53010308; called by muse, mutect2
- CHAT | c.21G>A p.K7= | Silent (SNP) | VAF 16/197 reads (8%) | called by muse, mutect2
- CLTCL1 | c.4770C>T p.N1590= (on ENST00000427926 / NM_007098.4; = p.N1533= on NM_001835.4) | Silent (SNP) | VAF 29/501 reads (6%) | called by muse, mutect2
- COL14A1 | c.960C>T p.F320= | Silent (SNP) | VAF 30/546 reads (5%) | catalogued as rs267601749, COSV52847587; called by muse, mutect2
- COL22A1 | c.2433C>T p.F811= | Silent (SNP) | VAF 35/443 reads (8%) | catalogued as rs767824998; called by muse, mutect2
- COLEC10 | c.687G>A p.Q229= | Silent (SNP) | VAF 36/568 reads (6%) | called by muse, mutect2
- CSMD2 | c.1101C>T p.F367= | Silent (SNP) | VAF 57/300 reads (19%) | catalogued as COSV53901112; called by muse, mutect2, varscan2
- CTNND2 | c.2106G>A p.R702= | Silent (SNP) | VAF 30/400 reads (8%) | catalogued as COSV58933575; called by muse, mutect2
- DCN | c.147C>T p.S49= | Silent (SNP) | VAF 41/584 reads (7%) | catalogued as rs899227075; called by muse, mutect2
- DENND2B | c.531G>A p.A177= | Silent (SNP) | VAF 42/623 reads (7%) | catalogued as rs754917286; called by muse, mutect2
- DGKZ | c.2676C>T p.A892= (on ENST00000454345 / NM_001105540.2; = p.A704= on NM_003646.4) | Silent (SNP) | VAF 38/410 reads (9%) | catalogued as rs1183144606; called by muse, mutect2
- DNAH6 | c.9594G>A p.L3198= | Silent (SNP) | VAF 38/384 reads (10%) | called by muse, mutect2
- DNAH7 | c.6858C>T p.I2286= | Silent (SNP) | VAF 34/496 reads (7%) | catalogued as rs771896188, COSV100415626, COSV56765911; called by muse, mutect2
- DNAJB8 | c.555C>T p.S185= | Silent (SNP) | VAF 53/639 reads (8%) | catalogued as COSV100048099; called by muse, mutect2
- DOCK7 | c.105A>G p.K35= | Silent (SNP) | VAF 96/396 reads (24%) | called by muse, mutect2, varscan2
- DPP3 | c.93C>T p.R31= | Silent (SNP) | VAF 59/618 reads (10%) | catalogued as COSV57857387; called by muse, mutect2
- DPPA4 | c.522G>A p.G174= | Silent (SNP) | VAF 55/622 reads (9%) | called by muse, mutect2
- DSCAM | c.1602C>T p.S534= | Silent (SNP) | VAF 56/657 reads (9%) | called by muse, mutect2
- DUSP22 | c.393C>T p.F131= | Silent (SNP) | VAF 85/826 reads (10%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.10524C>T p.L3508= | Silent (SNP) | VAF 42/410 reads (10%) | catalogued as rs931807854; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.141C>T p.S47= | Silent (SNP) | VAF 38/427 reads (9%) | called by muse, mutect2
- EFTUD2 | c.2400C>T p.P800= | Silent (SNP) | VAF 70/549 reads (13%) | called by muse, mutect2, varscan2
- EMC1 | c.948C>T p.F316= | Silent (SNP) | VAF 82/296 reads (28%) | catalogued as rs941175056; called by muse, mutect2, varscan2
- ENPP3 | c.1212C>T p.P404= | Silent (SNP) | VAF 26/378 reads (7%) | called by muse, mutect2
- ERG | c.399C>T p.I133= | Silent (SNP) | VAF 32/338 reads (9%) | catalogued as rs1473346716, COSV55727171; called by muse, mutect2
- FAM160A1 | c.447T>C p.S149= | Silent (SNP) | VAF 53/676 reads (8%) | catalogued as rs976908771; called by muse, mutect2
- FAM83B | c.1704C>T p.I568= | Silent (SNP) | VAF 40/551 reads (7%) | called by muse, mutect2
- FCRL3 | c.771T>G p.S257= | Silent (SNP) | VAF 46/509 reads (9%) | catalogued as COSV100942823, COSV63842650; called by muse, mutect2
- FLVCR2 | c.1368C>T p.S456= | Silent (SNP) | VAF 28/428 reads (7%) | called by muse, mutect2
- GJD2 | c.912G>A p.R304= | Silent (SNP) | VAF 26/454 reads (6%) | called by muse, mutect2
- GPR50 | c.687A>G p.Q229= | Silent (SNP) | VAF 58/750 reads (8%) | catalogued as rs779863949; called by muse, mutect2
- GRM3 | c.837C>T p.D279= | Silent (SNP) | VAF 41/754 reads (5%) | catalogued as COSV100862885, COSV64467042; called by muse, mutect2
- GSE1 | c.1287G>A p.S429= | Silent (SNP) | VAF 42/519 reads (8%) | catalogued as rs765549016; called by muse, mutect2
- HEATR1 | c.291C>T p.F97= | Silent (SNP) | VAF 80/418 reads (19%) | called by muse, mutect2, varscan2
- HECTD3 | c.1842C>T p.F614= | Silent (SNP) | VAF 69/297 reads (23%) | catalogued as COSV64670109; called by muse, mutect2, varscan2
- HNRNPLL | c.81C>T p.T27= | Silent (SNP) | VAF 56/626 reads (9%) | called by muse, mutect2
- ICAM1 | c.441C>T p.T147= | Silent (SNP) | VAF 66/686 reads (10%) | catalogued as rs377323164; called by muse, mutect2
- IMPG1 | c.240C>T p.V80= | Silent (SNP) | VAF 46/552 reads (8%) | catalogued as COSV100886198; called by muse, mutect2
- IRAG2 | c.3516C>T p.I1172= (on ENST00000636465; = p.I217= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 28/434 reads (6%) | called by muse, mutect2
- ITGAD | c.1566A>G p.A522= | Silent (SNP) | VAF 46/493 reads (9%) | called by muse, mutect2
- ITPR3 | c.6516C>T p.F2172= | Silent (SNP) | VAF 35/392 reads (9%) | called by muse, mutect2
- JAKMIP1 | c.1191C>T p.F397= | Silent (SNP) | VAF 31/476 reads (7%) | catalogued as COSV51529958; called by muse, mutect2
- KCNH1 | c.700T>C p.L234= | Silent (SNP) | VAF 42/546 reads (8%) | catalogued as rs763362705; called by muse, mutect2
- KIAA0513 | c.138G>A p.E46= | Silent (SNP) | VAF 90/627 reads (14%) | called by muse, mutect2, varscan2
- KIF13B | c.3441C>T p.P1147= | Silent (SNP) | VAF 49/569 reads (9%) | catalogued as COSV72954519; called by muse, mutect2
- KIF5C | c.1515G>A p.V505= | Silent (SNP) | VAF 52/620 reads (8%) | called by muse, mutect2
- KLK2 | c.63C>T p.I21= | Silent (SNP) | VAF 26/372 reads (7%) | catalogued as COSV57569043; called by muse, mutect2
- KRT74 | c.894C>T p.S298= | Silent (SNP) | VAF 41/386 reads (11%) | catalogued as rs867373376; called by muse, mutect2, varscan2
- KRTAP4-1 | c.177C>T p.C59= | Silent (SNP) | VAF 58/665 reads (9%) | called by muse, mutect2
- LAMA3 | c.5043C>T p.T1681= (on ENST00000313654 / NM_198129.4; = p.T72= on NM_000227.6) | Silent (SNP) | VAF 34/374 reads (9%) | catalogued as rs758486434; called by muse, mutect2
- LIFR | c.552C>T p.L184= | Silent (SNP) | VAF 27/204 reads (13%) | catalogued as rs370454146; ClinVar: likely benign; called by muse, mutect2, varscan2
- LMTK3 | c.2904G>A p.R968= | Silent (SNP) | VAF 73/658 reads (11%) | called by muse, mutect2, varscan2
- LRP2BP | c.321T>G p.T107= | Silent (SNP) | VAF 22/343 reads (6%) | called by muse, mutect2
- LRP8 | c.789C>T p.S263= | Silent (SNP) | VAF 167/544 reads (31%) | called by muse, mutect2, varscan2
- MAPK11 | c.432C>T p.A144= | Silent (SNP) | VAF 44/612 reads (7%) | called by muse, mutect2
- MAPT | c.1497C>T p.I499= (on ENST00000262410 / NM_001377265.1; = p.I424= on NM_016835.4) | Silent (SNP) | VAF 80/834 reads (10%) | called by muse, mutect2
- MEGF8 | c.81G>C p.A27= | Silent (SNP) | VAF 70/816 reads (9%) | called by muse, mutect2
- MGAT4D | c.339G>A p.R113= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as rs1055219312; called by muse, mutect2
- MISP | c.1017C>T p.A339= | Silent (SNP) | VAF 61/647 reads (9%) | catalogued as rs1182466493; called by muse, mutect2
- MROH2B | c.4383C>T p.P1461= | Silent (SNP) | VAF 30/386 reads (8%) | called by muse, mutect2
- MSH5 | c.1920C>T p.S640= | Silent (SNP) | VAF 54/523 reads (10%) | called by muse, mutect2, varscan2
- MTUS2 | c.1386G>A p.G462= | Silent (SNP) | VAF 44/597 reads (7%) | catalogued as COSV70923101; called by muse, mutect2
- MUC16 | c.11301C>T p.T3767= | Silent (SNP) | VAF 40/528 reads (8%) | catalogued as rs371375608; called by muse, mutect2
- MUC16 | c.3975C>T p.I1325= | Silent (SNP) | VAF 46/528 reads (9%) | called by muse, mutect2
- MYH13 | c.156C>T p.I52= | Silent (SNP) | VAF 46/396 reads (12%) | catalogued as rs759213643; called by muse, mutect2, varscan2
- MYO15B | c.3156C>T p.A1052= | Silent (SNP) | VAF 57/616 reads (9%) | called by muse, mutect2
- MYO5B | c.189G>A p.R63= | Silent (SNP) | VAF 41/419 reads (10%) | called by muse, mutect2, varscan2
- MYO9B | c.6369C>T p.A2123= | Silent (SNP) | VAF 62/639 reads (10%) | catalogued as COSV55726711; called by muse, mutect2
- NEXMIF | c.4084C>T p.L1362= | Silent (SNP) | VAF 41/558 reads (7%) | catalogued as COSV99280359; called by muse, mutect2
- NEXMIF | c.3078C>T p.F1026= | Silent (SNP) | VAF 46/668 reads (7%) | catalogued as COSV50180872; called by muse, mutect2
- NFASC | c.2151C>T p.S717= (on ENST00000339876 / NM_001378329.1; = p.S713= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/364 reads (15%) | catalogued as rs776480436, COSV100362452; called by muse, mutect2, varscan2
- NHS | c.21C>T p.I7= | Silent (SNP) | VAF 34/322 reads (11%) | called by muse, mutect2, varscan2
- NR2F1 | c.1158G>A p.E386= | Silent (SNP) | VAF 47/536 reads (9%) | called by muse, mutect2
- NUTM1 | c.1005G>A p.K335= | Silent (SNP) | VAF 33/437 reads (8%) | called by muse, mutect2
- OGDHL | c.690G>A p.V230= | Silent (SNP) | VAF 29/428 reads (7%) | catalogued as COSV65103261; called by muse, mutect2
- OR13C4 | c.435T>G p.T145= | Silent (SNP) | VAF 48/546 reads (9%) | catalogued as COSV52928644; called by muse, mutect2
- OR1M1 | c.588G>A p.R196= | Silent (SNP) | VAF 41/534 reads (8%) | catalogued as COSV70037427; called by muse, mutect2
- OR2M3 | c.642C>T p.I214= | Silent (SNP) | VAF 70/514 reads (14%) | called by muse, mutect2, varscan2
- OR51E1 | c.96C>T p.F32= | Silent (SNP) | VAF 45/515 reads (9%) | catalogued as COSV101211459; called by muse, mutect2
- OR51E2 | c.84C>T p.F28= | Silent (SNP) | VAF 30/526 reads (6%) | catalogued as COSV101211350; called by muse, mutect2
- OR51M1 | c.132C>T p.F44= | Silent (SNP) | VAF 48/548 reads (9%) | catalogued as COSV100150121, COSV60784116; called by muse, mutect2
- OTOGL | c.6834G>A p.R2278= (on ENST00000547103; = p.R2269= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/401 reads (10%) | catalogued as rs1164508853, COSV54022955; called by muse, mutect2
- OTOL1 | c.1290C>T p.L430= | Silent (SNP) | VAF 40/534 reads (7%) | catalogued as rs759583673, COSV60005967, COSV60008443; called by muse, mutect2
- PAPLN | c.3186G>A p.R1062= (on ENST00000554301; = p.R1035= on NM_173462.4) | Silent (SNP) | VAF 50/693 reads (7%) | called by muse, mutect2
- PCDH7 | c.411C>T p.N137= | Silent (SNP) | VAF 44/528 reads (8%) | catalogued as COSV62337107; called by muse, mutect2
- PCDHB6 | c.2062C>T p.L688= | Silent (SNP) | VAF 59/898 reads (7%) | catalogued as COSV50689552; called by muse, mutect2
- PCED1B | c.564C>T p.F188= | Silent (SNP) | VAF 28/501 reads (6%) | called by muse, mutect2
- PFKFB3 | c.1704C>T p.S568= | Silent (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- PHKA1 | c.1860C>T p.D620= | Silent (SNP) | VAF 52/561 reads (9%) | catalogued as rs781901926; called by muse, mutect2
- PHLDB1 | c.2628C>T p.S876= | Silent (SNP) | VAF 48/500 reads (10%) | catalogued as rs1555117825; called by muse, mutect2
- PIEZO2 | c.7020C>T p.L2340= | Silent (SNP) | VAF 28/348 reads (8%) | catalogued as rs746390950, COSV53289560; called by muse, mutect2
- PIK3C2A | c.372C>T p.S124= | Silent (SNP) | VAF 37/469 reads (8%) | called by muse, mutect2
- PLBD1 | c.627C>T p.L209= | Silent (SNP) | VAF 50/564 reads (9%) | called by muse, mutect2
- PLCB4 | c.1887C>T p.V629= | Silent (SNP) | VAF 42/288 reads (15%) | catalogued as rs145620817; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1665C>T p.F555= | Silent (SNP) | VAF 40/552 reads (7%) | called by muse, mutect2
- PPP1R37 | c.1527G>A p.S509= | Silent (SNP) | VAF 44/659 reads (7%) | catalogued as rs937602763; called by muse, mutect2
- PRDM10 | c.2700C>A p.T900= | Silent (SNP) | VAF 56/644 reads (9%) | called by muse, mutect2
- PRLR | c.1027C>T p.L343= | Silent (SNP) | VAF 46/625 reads (7%) | called by muse, mutect2
- PSG6 | c.607C>T p.L203= | Silent (SNP) | VAF 34/647 reads (5%) | catalogued as rs770764386; called by muse, mutect2
- PTGR2 | c.964T>C p.L322= | Silent (SNP) | VAF 31/339 reads (9%) | called by muse, mutect2
- RBM12B | c.519C>T p.V173= | Silent (SNP) | VAF 35/464 reads (8%) | catalogued as COSV66968391; called by muse, mutect2
- RBM47 | c.501C>T p.I167= | Silent (SNP) | VAF 46/656 reads (7%) | called by muse, mutect2
- REPIN1 | c.966G>A p.Q322= | Silent (SNP) | VAF 51/686 reads (7%) | called by muse, mutect2
- RGP1 | c.1126C>T p.L376= | Silent (SNP) | VAF 47/464 reads (10%) | called by muse, mutect2, varscan2
- RIMS1 | c.900C>T p.P300= | Silent (SNP) | VAF 48/602 reads (8%) | catalogued as COSV53467614; called by muse, mutect2
- ROBO4 | c.1218G>A p.L406= | Silent (SNP) | VAF 48/531 reads (9%) | called by muse, mutect2
- RPS19 | c.42C>T p.F14= | Silent (SNP) | VAF 18/444 reads (4%) | called by muse, mutect2
- RUFY4 | c.1581C>T p.I527= | Silent (SNP) | VAF 46/392 reads (12%) | catalogued as rs1369231592; called by muse, mutect2, varscan2
- RYK | c.1404C>T p.D468= (on ENST00000620660 / NM_001005861.2; = p.D465= on NM_002958.4) | Silent (SNP) | VAF 43/381 reads (11%) | called by muse, mutect2, varscan2
- SALL1 | c.3174C>T p.S1058= | Silent (SNP) | VAF 84/553 reads (15%) | catalogued as COSV51763700; called by muse, mutect2, varscan2
- SAMD12 | c.30G>A p.L10= | Silent (SNP) | VAF 28/352 reads (8%) | catalogued as COSV59049479; called by muse, mutect2
- SCN9A | c.5379G>A p.A1793= (on ENST00000303354; = p.A1782= on NM_002977.3) | Silent (SNP) | VAF 32/504 reads (6%) | catalogued as rs201875421; ClinVar: uncertain significance / benign; called by muse, mutect2
- SEZ6L | c.294C>T p.A98= | Silent (SNP) | VAF 70/736 reads (10%) | catalogued as rs1569448044; called by muse, mutect2
- SH3PXD2B | c.1947C>T p.S649= | Silent (SNP) | VAF 64/510 reads (13%) | called by muse, mutect2, varscan2
- SLC10A2 | c.888C>T p.F296= | Silent (SNP) | VAF 28/402 reads (7%) | catalogued as rs201615316, COSV55361645; called by muse, mutect2
- SLC35B1 | c.678C>G p.S226= (on ENST00000649906; = p.S189= on NM_005827.4) | Silent (SNP) | VAF 22/401 reads (5%) | called by muse, mutect2
- SLC6A20 | c.351C>T p.F117= | Silent (SNP) | VAF 35/441 reads (8%) | catalogued as rs1230328853; called by muse, mutect2
- SLC6A5 | c.1929C>T p.I643= | Silent (SNP) | VAF 37/346 reads (11%) | catalogued as rs774551994, COSV100116800; called by muse, mutect2, varscan2
- SLC7A4 | c.903C>T p.P301= | Silent (SNP) | VAF 85/583 reads (15%) | catalogued as rs377216630; called by muse, mutect2, varscan2
- SLC8A3 | c.540C>T p.I180= | Silent (SNP) | VAF 34/478 reads (7%) | catalogued as rs866796123; called by muse, mutect2
- SMC1B | c.2496G>A p.L832= | Silent (SNP) | VAF 87/458 reads (19%) | catalogued as COSV100663488; called by muse, mutect2, varscan2
- SMG9 | c.801C>T p.F267= | Silent (SNP) | VAF 32/411 reads (8%) | called by muse, mutect2
- SOX17 | c.1062C>T p.L354= | Silent (SNP) | VAF 69/748 reads (9%) | catalogued as COSV52026322, COSV99810640; called by muse, mutect2
- SP7 | c.1107G>A p.L369= | Silent (SNP) | VAF 56/600 reads (9%) | catalogued as rs751043035; called by muse, mutect2
- SPTA1 | c.4170C>T p.I1390= | Silent (SNP) | VAF 58/346 reads (17%) | catalogued as COSV100934523; called by muse, mutect2, varscan2
- SPTB | c.3021C>T p.I1007= | Silent (SNP) | VAF 60/682 reads (9%) | called by muse, mutect2
- SSU72P8 | c.408G>A p.V136= | Silent (SNP) | VAF 46/738 reads (6%) | called by muse, mutect2
- STAB2 | c.7341A>G p.K2447= | Silent (SNP) | VAF 40/484 reads (8%) | called by muse, mutect2
- STS | c.903A>C p.G301= | Silent (SNP) | VAF 32/447 reads (7%) | called by muse, mutect2
- TCEAL4 | c.621G>A p.R207= | Silent (SNP) | VAF 41/494 reads (8%) | called by muse, mutect2
- TFIP11 | c.2223G>A p.K741= | Silent (SNP) | VAF 80/457 reads (18%) | called by muse, mutect2, varscan2
- TMEM232 | c.1959G>A p.R653= | Silent (SNP) | VAF 24/228 reads (11%) | called by muse, mutect2, varscan2
- TP63 | c.1740C>T p.S580= | Silent (SNP) | VAF 24/382 reads (6%) | catalogued as COSV53223129; called by muse, mutect2
- TRANK1 | c.5278T>C p.L1760= | Silent (SNP) | VAF 37/429 reads (9%) | catalogued as rs377102985; called by muse, mutect2
- TREML2 | c.681C>T p.S227= | Silent (SNP) | VAF 57/634 reads (9%) | catalogued as COSV72439040; called by muse, mutect2
- TTN | c.75915C>T p.D25305= (on ENST00000591111; = p.D17881= on NM_003319.4) | Silent (SNP) | VAF 34/512 reads (7%) | called by muse, mutect2
- TTN | c.31296C>T p.S10432= (on ENST00000591111; = p.S9505= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/485 reads (6%) | catalogued as COSV60078652; called by muse, mutect2
- UBR2 | c.129C>T p.A43= | Silent (SNP) | VAF 42/452 reads (9%) | catalogued as rs751933543; called by muse, mutect2
- UGT3A1 | c.510C>T p.F170= | Silent (SNP) | VAF 42/627 reads (7%) | catalogued as rs184080185, COSV57096721; called by muse, mutect2
- USH1C | c.69G>A p.K23= | Silent (SNP) | VAF 40/443 reads (9%) | called by muse, mutect2
- VIRMA | c.1338C>T p.R446= | Silent (SNP) | VAF 56/627 reads (9%) | called by muse, mutect2
- VNN1 | c.169C>T p.L57= | Silent (SNP) | VAF 31/447 reads (7%) | called by muse, mutect2
- VSTM2A | c.201G>A p.R67= | Silent (SNP) | VAF 90/528 reads (17%) | called by muse, mutect2, varscan2
- WASHC2A | c.1818C>T p.S606= | Silent (SNP) | VAF 30/420 reads (7%) | catalogued as rs782259216; called by muse, mutect2
- WDFY4 | c.1479C>T p.I493= | Silent (SNP) | VAF 31/472 reads (7%) | catalogued as rs368931313, COSV57442268; called by muse, mutect2
- WDR97 | c.2793C>T p.S931= | Silent (SNP) | VAF 60/571 reads (11%) | called by muse, mutect2, varscan2
- WNK2 | c.4702C>T p.L1568= (on ENST00000297954 / NM_001282394.1; = p.L1531= on NM_006648.3) | Silent (SNP) | VAF 46/688 reads (7%) | called by muse, mutect2
- ZNF219 | c.1272G>A p.E424= | Silent (SNP) | VAF 66/832 reads (8%) | catalogued as rs1365819319; called by muse, mutect2
- ZNF276 | c.1044G>A p.S348= (on ENST00000443381 / NM_001113525.2; = p.S273= on NM_152287.4) | Silent (SNP) | VAF 56/570 reads (10%) | catalogued as rs1347675024, COSV57072463; called by muse, mutect2
- ZNF280D | c.2772C>T p.S924= | Silent (SNP) | VAF 40/584 reads (7%) | catalogued as rs766589156; called by muse, mutect2
- ZNF384 | c.735C>T p.I245= | Silent (SNP) | VAF 38/450 reads (8%) | called by muse, mutect2
- ZNF423 | c.1791G>A p.K597= (on ENST00000563137 / NM_001379286.1; = p.K589= on NM_015069.4) | Silent (SNP) | VAF 98/574 reads (17%) | catalogued as rs770863927; called by muse, varscan2
- ZNF646 | c.3567C>T p.A1189= | Silent (SNP) | VAF 46/585 reads (8%) | catalogued as rs201707459, COSV99762148; called by muse, mutect2
- ZNF646 | c.5001C>T p.S1667= | Silent (SNP) | VAF 62/683 reads (9%) | called by muse, mutect2
- ZNF729 | c.145C>T p.L49= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- ZSWIM2 | c.12A>C p.R4= | Silent (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- A1CF | c.100-6589G>A | Intron (SNP) | VAF 28/462 reads (6%) | catalogued as rs866557835, COSV50957623; called by muse, mutect2
- AL353804.7 | chrX:73849939 G>A | 5'Flank (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- ATP2B2 | c.908-1165C>T | Intron (SNP) | VAF 44/538 reads (8%) | catalogued as COSV59506545; called by muse, mutect2
- C2CD6 | c.1581+3413G>A | Intron (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- CSAG1 | c.167+28C>T | Intron (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- DGLUCY | c.257+239C>T | Intron (SNP) | VAF 36/528 reads (7%) | catalogued as rs1483247403; called by muse, mutect2
- KCNQ1 | c.1394-20526C>T | Intron (SNP) | VAF 32/356 reads (9%) | called by muse, mutect2
- KCNQ1 | c.1394-19837G>A | Intron (SNP) | VAF 35/373 reads (9%) | called by muse, mutect2
- LINC00968 | n.293G>A | RNA (SNP) | VAF 26/408 reads (6%) | called by muse, mutect2
- LTN1 | chr21:28992910 C>T | 5'Flank (SNP) | VAF 37/442 reads (8%) | catalogued as rs1463740631, COSV100239041, COSV57478221; called by muse, mutect2
- MBD5 | c.2845+414C>T | Intron (SNP) | VAF 24/354 reads (7%) | called by muse, mutect2
- MECOM | c.-13G>A | 5'UTR (SNP) | VAF 22/397 reads (6%) | called by muse, mutect2
- MGAM | c.4618+13360C>T | Intron (SNP) | VAF 49/401 reads (12%) | called by muse, mutect2, varscan2
- MGAM | c.4619-12462G>A | Intron (SNP) | VAF 36/661 reads (5%) | called by muse, mutect2
- MGAM | c.4619-11239A>C | Intron (SNP) | VAF 42/580 reads (7%) | catalogued as COSV101527714; called by muse, mutect2
- MGAM | c.4619-10016C>T | Intron (SNP) | VAF 28/544 reads (5%) | catalogued as rs779350259; called by muse, mutect2
- OR10D3 | c.-1C>T | 5'UTR (SNP) | VAF 38/340 reads (11%) | called by muse, mutect2
- PSG3 | c.*153C>T | 3'UTR (SNP) | VAF 19/451 reads (4%) | called by muse, mutect2
- PTPRT | c.*6104G>A | 3'UTR (SNP) | VAF 60/356 reads (17%) | called by muse, mutect2, varscan2
- RXFP1 | c.465-867C>T | Intron (SNP) | VAF 44/500 reads (9%) | called by muse, mutect2
- TTN | c.10303+2564G>A | Intron (SNP) | VAF 43/450 reads (10%) | catalogued as COSV59949448; called by muse, mutect2
- USP8 | c.-159C>T | 5'UTR (SNP) | VAF 31/387 reads (8%) | catalogued as rs1451441167; called by muse, mutect2
- UVSSA | c.*9266C>T | 3'UTR (SNP) | VAF 56/701 reads (8%) | catalogued as rs760129440; called by muse, mutect2
- Z99774.2 | chr22:26673093 G>A | 3'Flank (SNP) | VAF 34/317 reads (11%) | called by muse, mutect2, varscan2
- ZNF812P | n.554A>C | RNA (SNP) | VAF 18/314 reads (6%) | called by muse, mutect2
